Somatic mutation profile of tumor specimen TCGA-DD-AAE0-01A (aliquot TCGA-DD-AAE0-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G4; Age at diagnosis: 45.8 years (16,732 days).
Specimen TCGA-DD-AAE0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed915a7e-afb4-4af0-b3fd-ff6b2f603b47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE0-10A (Blood Derived Normal), aliquot TCGA-DD-AAE0-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb72682f-e615-4dbf-bff7-bbf1d50df4e0

The open-access MAF lists 79 somatic variants for this specimen: 55 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 21, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1250T>A p.V417D | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99328682; called by muse, mutect2, varscan2
- ADCY10 | c.1790A>G p.N597S | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100896907; called by muse, mutect2, varscan2
- ADGRE5 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs781751037, COSV99662690, COSV99662979; called by muse, mutect2, varscan2
- ADRM1 | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV53386936, COSV99445645; called by muse, mutect2, varscan2
- AFF2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99664531; called by muse, mutect2, varscan2
- AHDC1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV99899425; called by muse, mutect2, varscan2
- ARHGAP27 | c.1741G>A p.E581K (on ENST00000428638 / NM_001282290.1; = p.E240K on NM_199282.3) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100976549; called by muse, mutect2, varscan2
- ARHGEF40 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100070434; called by muse, mutect2, varscan2
- ATP1A3 | c.1408G>A p.V470M (on ENST00000545399 / NM_001256214.2; = p.V457M on NM_152296.5) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100132315; called by muse, mutect2, varscan2
- ATRAID | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100143343; called by muse, mutect2
- CDT1 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 61/82 reads (74%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV99967254; called by muse, mutect2, varscan2
- CYP11B1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as COSV99455236; called by muse, mutect2, varscan2
- CYP2A13 | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV100386841; called by muse, mutect2, varscan2
- DRC1 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99985446; called by muse, mutect2, varscan2
- EIF4G3 | c.3137T>C p.V1046A | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.195); catalogued as COSV99944625; called by muse, mutect2, varscan2
- EP300 | c.2893C>G p.Q965E | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as COSV99608898, COSV99609652; called by muse, mutect2, varscan2
- FAM47A | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.85); catalogued as COSV100649944; called by muse, mutect2, varscan2
- FIG4 | c.1392G>A p.W464* | Nonsense Mutation (SNP) | VAF 51/126 reads (40%) | catalogued as rs1478560628, COSV100019792; called by muse, mutect2, varscan2
- GEN1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100438032; called by muse, mutect2, varscan2
- HDC | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV99983768; called by muse, mutect2, varscan2
- HPN | c.133A>T p.R45W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV99385163; called by muse, mutect2
- IFI44L | c.579C>A p.D193E | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100655012; called by muse, mutect2, varscan2
- IGFL2 | c.166G>A p.A56T (on ENST00000377693 / NM_001135113.2; = p.A67T on NM_001002915.2) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs754195953, COSV66616668; called by muse, mutect2, varscan2
- IGSF9B | c.208C>G p.P70A | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100317847; called by muse, mutect2, varscan2
- IQGAP3 | c.1454T>C p.F485S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as COSV100752183; called by muse, mutect2, varscan2
- ITGAD | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs752180420, COSV66756814; called by muse, mutect2, varscan2
- KDELR2 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99330630; called by muse, mutect2
- KIF5C | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101276151; called by muse, mutect2
- KRT9 | c.814T>A p.S272T | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.091); catalogued as COSV99879250; called by muse, mutect2, varscan2
- LPCAT4 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.058); catalogued as rs757794901, COSV100149042; called by muse, mutect2
- LRFN3 | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV99873403; called by muse, mutect2, varscan2
- LRP1B | c.10378C>T p.P3460S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as rs1450675840, COSV101257804; called by muse, mutect2, varscan2
- MED12L | c.5358G>T p.Q1786H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.948); catalogued as COSV99853553; called by muse, mutect2, varscan2
- NYAP1 | c.974del p.P325Rfs*106 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | catalogued as COSV55721210; called by mutect2, pindel, varscan2
- OR10S1 | c.523T>G p.S175A | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101602484; called by muse, mutect2, varscan2
- OTOF | c.3746G>A p.R1249Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200312028, COSV99717954; called by muse, mutect2, varscan2
- PCDHGA1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as COSV65295207; called by muse, mutect2, varscan2
- PRDM13 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs770384917, COSV65030735; called by muse, mutect2, varscan2
- RAD50 | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99529102; called by muse, mutect2, varscan2
- RBM28 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV56164117, COSV99775753; called by muse, mutect2, varscan2
- RNF128 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99718262; called by muse, mutect2, varscan2
- SBK2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs1414121177, COSV100705156; called by muse, mutect2, varscan2
- SGPL1 | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100940391; called by muse, mutect2, varscan2
- SLC22A15 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760335203, COSV101047292; called by muse, mutect2, varscan2
- SLC25A45 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as rs867092318, COSV99587344; called by muse, mutect2, varscan2
- SMAD4 | c.289del p.R97Vfs*13 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as COSV100748245; called by mutect2, pindel, varscan2
- STAG2 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.191); catalogued as COSV99493451; called by muse, mutect2, varscan2
- TCTN3 | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99797173; called by muse, mutect2, varscan2
- THEMIS | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs868167768, COSV64069556, COSV64070385; called by muse, mutect2, varscan2
- TP53 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV52783299, COSV52873550, COSV52906834; called by muse, mutect2, varscan2
- ZNF148 | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100642125; called by muse, mutect2, varscan2
- ZNF521 | c.2977T>A p.C993S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100832481; called by muse, mutect2, varscan2
- ZSCAN10 | c.1747G>T p.E583* (on ENST00000252463; = p.E638* on NM_032805.3) | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV52970582, COSV99374112; called by muse, mutect2, varscan2
- FAM217A | c.226dup p.S76Kfs*5 | Frame Shift Ins (INS) | VAF 146/414 reads (35%) | called by mutect2, varscan2
- ABCC5 | c.3084G>T p.L1028= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV99657044; called by muse, mutect2, varscan2
- ADI1 | c.27C>T p.D9= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100537779; called by muse, mutect2, varscan2
- CCDC102B | c.69T>A p.I23= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100103799; called by muse, mutect2, varscan2
- CHD6 | c.4761C>T p.G1587= | Silent (SNP) | VAF 20/147 reads (14%) | catalogued as COSV100951116; called by muse, mutect2, varscan2
- FLT1 | c.429C>T p.P143= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs537466636, COSV56723242, COSV56726972; called by muse, mutect2, varscan2
- HERC2 | c.9588C>T p.P3196= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV99874534; called by muse, mutect2, varscan2
- IL2RB | c.1389C>A p.V463= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs766135944, COSV99344989, COSV99345208; called by muse, mutect2, varscan2
- KLHL4 | c.1383C>T p.T461= | Silent (SNP) | VAF 28/193 reads (15%) | catalogued as COSV100909733; called by muse, mutect2, varscan2
- LRRN2 | c.87C>T p.C29= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs767887975, COSV100912891; called by muse, mutect2, varscan2
- MGLL | c.576C>T p.D192= (on ENST00000398104 / NM_001003794.2; = p.D202= on NM_007283.6) | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV99411968; called by muse, mutect2, varscan2
- NACA2 | c.513C>T p.V171= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV101478550; called by muse, mutect2, varscan2
- OR5AP2 | c.120C>A p.I40= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV100266261, COSV57258078; called by muse, mutect2, varscan2
- PALLD | c.1092C>T p.A364= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99824991; called by muse, mutect2, varscan2
- PARP4 | c.408T>C p.G136= | Silent (SNP) | VAF 131/330 reads (40%) | catalogued as rs139683851; called by muse, mutect2, varscan2
- PDGFRB | c.1815C>T p.T605= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV55805080, COSV99940714; called by muse, mutect2, varscan2
- PMFBP1 | c.105A>G p.R35= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV99401018; called by muse, mutect2, varscan2
- PRELID3A | c.297A>G p.T99= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as COSV100426937; called by muse, mutect2, varscan2
- PRRC2A | c.3744T>G p.A1248= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV101051220; called by muse, mutect2, varscan2
- RXFP3 | c.210G>A p.G70= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV100347597; called by muse, mutect2
- SLIT2 | c.1642T>C p.L548= | Silent (SNP) | VAF 86/256 reads (34%) | catalogued as rs761101181, COSV99884603; called by muse, mutect2, varscan2
- TRAP1 | c.1668G>A p.V556= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs1435632495, COSV99893597; called by muse, mutect2, varscan2
- DCT | c.1179+7441C>T | Intron (SNP) | VAF 25/46 reads (54%) | catalogued as rs192427783, COSV65469702, COSV65469848; called by muse, mutect2, varscan2
- MIR513B | n.53T>C | RNA (SNP) | VAF 173/470 reads (37%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1550C>T | RNA (SNP) | VAF 85/156 reads (54%) | catalogued as rs368625378; called by muse, mutect2, varscan2
